Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A1D6, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A1D6-01A (Primary Tumor).

125-0-3
Adenocarcinoma, mucinous, NOS 8480/3
Site Code: Splenic flexure of colon C18.5

1/10/11
LW

(First Tumor)

Tumor Site:	Splenic Flexure Distal		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Moderately Differentiated		
Mucinous:	☐ No	☒ Yes	☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown
Host Response:	Lymphoid Aggregates		
Crohn's like reaction	☐ None	☒ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☐ Expansile	☒ Invasive	☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No	☐ Yes	☐ Unknown
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown
Mutator Phenotype:	☐ No	☒ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	0		
Pathologist Comment:			

Hist-Path Discrepancy		☒

Source: NCI Genomic Data Commons file c6d69e34-f142-4425-8fd8-bed6ccf50eca (TCGA-DM-A1D6.A73A51CC-5DDB-4D1D-ABDC-858856CC3B8D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).